MMRF case MMRF_2436 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3f6b75a7-1326-470b-8e3a-4558c813cd51

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.2 years (21,990 days); Days to last known disease status: 692 days (1.9 years); Days to last follow up: 692 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 27 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 215 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 27 days; Days to treatment end: 54 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 34 days; Days to treatment end: 215 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 54 days; Days to treatment end: 215 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 259 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 692.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 0.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 30.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1734 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 317 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.8 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 5.72 mmol/L.
- Day 98 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 26.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 23 mg/dL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 174 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 10.6 mmol/L.
- Day 152 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.6 mg/dL; Immunoglobulin G 5.6 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 174 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 5.7 g/dL; Glucose 6.38 mmol/L.
- Day 278 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 47.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 20.6 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 4.95 mmol/L.
- Day 376 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 39.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.7 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 5.06 mmol/L.
- Day 510 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 21.7 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 9.8 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 187 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 8 g/dL; Glucose 5.28 mmol/L.
- Day 594 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 20.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.7 mg/dL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 5.83 ×10⁹/L; Absolute Neutrophil 3.68 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 171 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 5.89 mmol/L.
- Day 685 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 10.2 mmol/L; Leukocytes 7.83 ×10⁹/L; Absolute Neutrophil 5.29 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 172 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.35 mmol/L; Albumin 46 g/L; Total Protein 8 g/dL; Glucose 4.35 mmol/L.

Other clinical attributes
- Day 1: Weight: 82 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Leukemia; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2436_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2436_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
